Gene-level copy-number profile of tumor specimen TCGA-VS-A9V4-01A from TCGA case TCGA-VS-A9V4, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 63.9 years (23,334 days).
Specimen TCGA-VS-A9V4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.e4905edb-59ab-4a12-a9b7-a00c988db840.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9V4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d135de9a-f76b-470b-bafc-fa4a702b6454

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,305; copy number 2: 16,224; copy number 3: 31,290; copy number 4: 2,116; copy number 5: 6,163; copy number 6: 1,651; copy number 7: 804; copy number 8: 29; copy number 11: 196; copy number 14: 8; copy number 17: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9V4-01A-12D-A42N-01): tumor purity 0.33, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,064 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–9,045,940, 186 genes, copy number 7 (broad region; genes not listed).
- chr5:9,053,816–9,053,895, 1 gene, copy number 7: MIR4636.
- chr5:9,511,333–45,895,970, 520 genes, copy number 7 (broad region; genes not listed).
- chr8:31,639,222–34,346,731, 37 genes, copy number 8–14 (within-gene range 1–14): NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3.
- chr9:29,824,742–31,506,615, 15 genes, copy number 7: ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30.
- chr17:37,084,992–42,121,367, 254 genes, copy number 7–17 (within-gene range 5–17) (broad region; genes not listed).
- chr17:42,122,804–42,123,352, 1 gene, copy number 17: HSPB9.
- chr19:28,435,388–28,727,680, 1 gene, copy number 7 (within-gene range 5–7): AC005394.2.
- chr19:28,491,864–31,147,981, 49 genes, copy number 7 (within-gene range 5–7): AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1.

Autosomal genes at a single copy (total copy number 1): 1,305. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
